Somatic mutation profile of tumor specimen 0DDC9V from CCDI case PBBNTF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 3.9 years (1,437 days).
Specimen 0DDC9V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6b5c419-9da9-44af-a337-999053f3869b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDC9W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f20e6c4-1038-4161-9909-d27cf790b3f0

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 3, Splice Region 2, 5'UTR 1, Splice Site 1, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004922.1 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 139/279 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as rs371760619; called by muse, mutect2, varscan2
- CABLES1 | c.1465G>A p.V489M (on ENST00000256925 / NM_001100619.2; = p.V224M on NM_138375.2) | Missense Mutation (SNP) | VAF 125/329 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs374881958; called by muse, mutect2, varscan2
- COL17A1 | c.2105C>A p.P702Q | Missense Mutation (SNP) | VAF 102/429 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.216); catalogued as COSV62225203; called by muse, mutect2, varscan2
- CPNE7 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 133/323 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs772899233, COSV52014078; called by muse, mutect2, varscan2
- CPXM2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 339/1162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779999511; called by muse, mutect2, varscan2
- DNAI4 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 377/889 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs746684080, COSV64017932; called by muse, mutect2, varscan2
- GFRA3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 102/438 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs140929912; called by muse, mutect2, varscan2
- KIAA0408 | c.1631C>G p.P544R | Missense Mutation (SNP) | VAF 258/915 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64106496; called by muse, mutect2, varscan2
- NRG2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 147/501 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs947701574, COSV56838133; called by muse, mutect2, varscan2
- OR1G1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 179/742 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100187578; called by muse, mutect2, varscan2
- SPOP | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 664/1078 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61652615; called by muse, mutect2, varscan2
- WASHC5 | c.2803G>T p.A935S | Missense Mutation (SNP) | VAF 68/2276 reads (3%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV100572365; called by muse, mutect2
- WDR27 | c.2649G>T p.L883F | Missense Mutation (SNP) | VAF 107/748 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.144); catalogued as COSV61217390; called by muse, mutect2, varscan2
- ACTR5 | c.1327T>G p.F443V | Missense Mutation (SNP) | VAF 234/1264 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ANHX | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 139/461 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ANK3 | c.11102C>A p.S3701Y | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CATSPERG | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 126/577 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEACAM18 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 147/561 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP4A11 | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 30/746 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2
- DAGLA | c.546G>T p.L182= | Splice Region (SNP) | VAF 168/562 reads (30%) | called by muse, mutect2, varscan2
- ENTHD1 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 263/632 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGFR1 | c.1285-4G>T | Splice Region (SNP) | VAF 99/510 reads (19%) | called by muse, mutect2, varscan2
- HRNR | c.7259G>A p.S2420N | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- JPH3 | c.1269C>A p.F423L | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MGAT1 | c.863G>T p.W288L | Missense Mutation (SNP) | VAF 131/459 reads (29%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRK | c.173_176dup p.K60Sfs*2 | Frame Shift Ins (INS) | VAF 202/267 reads (76%) | called by mutect2, varscan2
- OR8B3 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 242/844 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); called by mutect2, varscan2
- PARN | c.1714A>G p.S572G | Missense Mutation (SNP) | VAF 258/647 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POTEB3 | c.204C>A p.C68* | Nonsense Mutation (SNP) | VAF 80/474 reads (17%) | called by muse, varscan2
- RAB2A | c.363-3_363-2del p.X121_splice | Splice Site (DEL) | VAF 183/1108 reads (17%) | called by mutect2, varscan2
- RAB31 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 343/849 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- RALB | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 222/854 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RYR2 | c.2450C>A p.P817H | Missense Mutation (SNP) | VAF 308/723 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SERPINI2 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 232/1195 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC13A4 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 261/728 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D3L | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CCM2 | c.402G>T p.V134= | Silent (SNP) | VAF 128/320 reads (40%) | called by muse, mutect2
- CKAP5 | c.1659G>T p.G553= | Silent (SNP) | VAF 251/836 reads (30%) | called by muse, mutect2, varscan2
- CSMD1 | c.2424C>A p.V808= (on ENST00000520002; = p.V807= on NM_033225.6) | Silent (SNP) | VAF 100/525 reads (19%) | called by muse, mutect2, varscan2
- DDX43 | c.243G>A p.A81= | Silent (SNP) | VAF 114/457 reads (25%) | catalogued as rs767975138; called by muse, mutect2, varscan2
- EYS | c.8448C>A p.G2816= (on ENST00000370621 / NM_001292009.1; = p.G2795= on NM_001142800.2) | Silent (SNP) | VAF 32/1390 reads (2%) | called by muse, mutect2
- FREM1 | c.4470C>T p.T1490= | Silent (SNP) | VAF 222/582 reads (38%) | catalogued as rs766345217, COSV101083777; called by muse, mutect2, varscan2
- IDE | c.2811C>A p.I937= | Silent (SNP) | VAF 134/616 reads (22%) | called by mutect2, varscan2
- MYO5A | c.3360C>T p.N1120= | Silent (SNP) | VAF 45/866 reads (5%) | catalogued as rs191620408; called by muse, mutect2
- PCDH17 | c.2007C>A p.G669= | Silent (SNP) | VAF 109/465 reads (23%) | catalogued as COSV64971632; called by muse, mutect2, varscan2
- SLC15A2 | c.678G>A p.L226= | Silent (SNP) | VAF 232/543 reads (43%) | called by muse, mutect2, varscan2
- SMCO2 | c.153C>A p.I51= | Silent (SNP) | VAF 30/1182 reads (3%) | called by muse, mutect2
- TUBB1 | c.1218C>T p.N406= | Silent (SNP) | VAF 332/731 reads (45%) | catalogued as rs758400105; called by muse, mutect2, varscan2
- ZNF112 | c.1101C>A p.A367= (on ENST00000337401 / NM_001083335.2; = p.A361= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 66/1154 reads (6%) | called by muse, mutect2
- ADAM11 | c.1393-25C>T | Intron (SNP) | VAF 51/164 reads (31%) | catalogued as rs755352250; called by muse, mutect2, varscan2
- FGF1 | c.-13C>A | 5'UTR (SNP) | VAF 32/735 reads (4%) | called by muse, mutect2
- HELZ2 | c.1731-33C>A | Intron (SNP) | VAF 10/292 reads (3%) | catalogued as rs1183349144; called by muse, mutect2
- IDH3B | c.531+27C>A | Intron (SNP) | VAF 28/477 reads (6%) | called by muse, mutect2
- TMEM38A | chr19:16660153 C>A | 5'Flank (SNP) | VAF 42/600 reads (7%) | catalogued as rs370207299, COSV99495300; called by muse, mutect2
